Gene-level copy-number profile of tumor specimen TCGA-EA-A3HU-01A from TCGA case TCGA-EA-A3HU, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 43.6 years (15,909 days).
Specimen TCGA-EA-A3HU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.fb8d3a71-3873-41fe-97ef-58a318ea8801.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EA-A3HU-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/d818f9ba-1135-4431-b702-3b65dd14f939

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,383; copy number 2: 3,862; copy number 4: 46,655; copy number 5: 159; copy number 6: 7,034; copy number 8: 724.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,383. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
